Surgical pathology report (de-identified scan), TCGA case TCGA-B9-4116, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-4116-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

TCGA-B9-4116

Surgical Pathology Report

Accession #:

Diagnosis:

Left kidney and ureter, nephroureterectomy

Histologic tumor type/subtype: Renal cell carcinoma,
papillary type (type 1)

Histologic grade (if applicable): Fuhrman nuclear grade 2
(of 4)

Tumor size (greatest dimension): 7.9 cm in greatest
dimension

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: Negative

Gerota' s fascia: Negative

Renal vein: Negative

Ureter: Negative (see comment)

Lymphovascular space invasion: Not identified

Histologic assessment of surgical margins:

Perirenal adipose tissue: Negative

Gerota' s fascia: Negative

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Other significant findings:

- Non-neoplastic kidney with severe atrophy and cystic
change

AJCC Staging: pT2a pNx

[page 2 of 3]
This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

Sections of ureter show free floating fragments of renal cell carcinoma within the ureteral lumen without invasion or involvement of the ureteral wall.

Clinical History:

The [REDACTED] is with a left renal mass.

Gross Description:

Specimen A received is one appropriately labeled container. The specimen label states "left nephroureterectomy."

Specimen fixation: formalin

Type of specimen: nephroureterectomy, left

Size and weight of specimen: 180 g, 15 x 9 x 6 cm overall

Orientation: The external surfaces of the specimen are inked blue. A 12.2 cm length of ureter is attached to the specimen.

Presence/absence of adrenal gland: absent

Tumor description/site: Grossly the tumor encompasses the entire kidney, and there is no normal-appearing kidney parenchyma identified. The cut surface of the tumor demonstrates a soft, necrotic, fleshy, and friable texture with a white-tan coloration. As the specimen is serially sectioned, plugs of tumor fall out of cavities in what appears to be a dilated renal pelvis.

Tumor size: 7.9 x 6.5 x 5.1 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: confined

Extent of invasion:

Perirenal adipose tissue: Not involved by tumor

Gerota's fascia: Not involved by tumor

[page 3 of 3]
Renal vein: Not involved by tumor
Ureter: Not involved by tumor
Other organs: not applicable

Surgical margins:
Perirenal adipose tissue: negative
Renal vein: negative
Renal artery: negative
Ureter: negative

Description of kidney away from tumor: There are multiple cysts (1.6 cm greatest dimension) with smooth linings located at the inferior pole of the kidney. The cysts are productive of thin, straw-colored fluid.

Lymph nodes (hilar): no lymph nodes are identified

Other significant findings: The ureter is serially sectioned and reveals the lumen of the proximal aspect to be filled with a maroon-red sludge-like material. Otherwise, the ureter is grossly unremarkable.

Tissue submitted for special investigations: Representative tumor and representative normal renal parenchyma is submitted to tissue procurement.

Digital photograph taken: none

Block Summary:

- A1 - vein and artery margins
- A2 - tumor at blue ink
- A3 - tumor at hilum
- A4 - tumor undermining renal pelvis
- A5 - representative cysts at inferior pole of kidney
- A6 - ?residual normal renal parenchyma
- A7 - tumor and ?normal appearing renal parenchyma
- A8 - additional representative tumor
- A9 - additional representative tumor (two separate pieces)
- A10 - representative cross sections of proximal half ureter
- A11 - ureteral margin

Source: NCI Genomic Data Commons file ab48626c-dae7-46e9-bd86-b216c449f54e (TCGA-B9-4116.6F37A5C5-3774-48A0-9541-B0B82BE54B00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).